Somatic mutation profile of tumor specimen TCGA-DA-A1I4-06A (aliquot TCGA-DA-A1I4-06A-11D-A196-08) from TCGA case TCGA-DA-A1I4, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.1 years (19,750 days).
Specimen TCGA-DA-A1I4-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ae85dc3-e37c-4f19-bdcb-600ad3c13507.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DA-A1I4-10A (Blood Derived Normal), aliquot TCGA-DA-A1I4-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7b68e3b5-3c0b-4c6c-b077-2185c253cc98

The open-access MAF lists 317 somatic variants for this specimen: 215 protein-altering or splice-affecting, 96 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 192, Silent 96, Nonsense Mutation 16, RNA 4, Splice Site 3, Frame Shift Del 3, Nonstop Mutation 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GCK | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 177/421 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs1554335566, CM096832, COSV60786479; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNB1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518621, COSV65565954; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCD4 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.611); catalogued as rs1436816390, COSV53991851; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2962G>A p.G988R | Missense Mutation (SNP) | VAF 31/229 reads (14%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as COSV55001072; called by muse, mutect2, varscan2
- ADGRV1 | c.5278G>A p.V1760M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV67983059; called by muse, mutect2, varscan2
- AFF3 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.786); catalogued as COSV57849974; called by muse, mutect2, varscan2
- ALG9 | c.1462C>T p.Q488* (on ENST00000614444 / NM_001352418.1; = p.Q495* on NM_024740.2) | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as rs782652453, COSV67644082; called by muse, mutect2, varscan2
- ALOXE3 | c.2009G>A p.R670Q | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.023); catalogued as rs780485184, COSV59073976; called by muse, mutect2, varscan2
- AMZ1 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as rs766281461, COSV56687453; called by muse, mutect2, varscan2
- ANGEL1 | c.1588C>T p.L530F | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1158161838, COSV51872712; called by muse, mutect2, varscan2
- ANK3 | c.5535T>A p.F1845L | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV55052521; called by muse, mutect2, varscan2
- ANKRD30A | c.3463G>A p.E1155K (on ENST00000611781; = p.E1099K on NM_052997.2) | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.019); catalogued as COSV64608195; called by muse, mutect2, varscan2
- ANPEP | c.1022C>T p.S341L | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.46); catalogued as COSV55590732; called by muse, mutect2, varscan2
- APOB | c.9478G>A p.E3160K | Missense Mutation (SNP) | VAF 144/567 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs999346511, COSV51931380; called by muse, mutect2, varscan2
- AQR | c.1126A>T p.T376S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs757643136, COSV50031873; called by muse, mutect2, varscan2
- ARID2 | c.2128C>T p.P710S | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as COSV57596580; called by muse, mutect2, varscan2
- ASCC2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as rs772979948, COSV57072978; called by muse, mutect2, varscan2
- BAG6 | c.1727C>A p.A576D (on ENST00000676571; = p.A529D on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/314 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV52991747; called by muse, mutect2, varscan2
- BRCA2 | c.8749C>T p.L2917F | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV66450046; called by muse, mutect2, varscan2
- BRD4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as rs1331613863, COSV54587817; called by muse, mutect2, varscan2
- CABP4 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.381); catalogued as COSV56886007; called by muse, mutect2, varscan2
- CAGE1 | c.484A>T p.K162* (on ENST00000512086; = p.K26* on NM_205864.3) | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as COSV57076318; called by muse, mutect2, varscan2
- CAPN6 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 150/287 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60694569; called by muse, mutect2, varscan2
- CCDC61 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV54428299; called by muse, mutect2, varscan2
- CCDC88C | c.1257G>T p.E419D | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV66236977; called by muse, mutect2, varscan2
- CCL11 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as rs56358892, COSV59924967; called by muse, mutect2, varscan2
- CDH10 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.272); catalogued as COSV52577229, COSV52581224; called by muse, mutect2, varscan2
- CEP120 | c.2142A>T p.K714N | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV60265007; called by muse, mutect2, varscan2
- CILP2 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52276051; called by muse, mutect2, varscan2
- CLCN6 | c.1900C>T p.P634S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1228325517, COSV56739303; called by muse, mutect2, varscan2
- CLP1 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.33); catalogued as COSV57054817; called by muse, mutect2, varscan2
- CLPB | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 95/303 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs1251647670, COSV53630585; called by muse, mutect2, varscan2
- CNGB1 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); catalogued as COSV51899776; called by muse, mutect2, varscan2
- CNTN4 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1195160321, COSV68568827; called by muse, mutect2, varscan2
- COL4A1 | c.1315C>T p.P439S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV65423941; called by muse, mutect2, varscan2
- COL4A3 | c.1242G>A p.M414I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV67414345; called by muse, mutect2, varscan2
- COL4A3 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101170225, COSV67414765; called by muse, mutect2, varscan2
- COL6A6 | c.4907G>A p.G1636E | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62022245; called by muse, mutect2, varscan2
- COL7A1 | c.6776C>T p.P2259L | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as CM152134, COSV100094746, COSV100096572; called by muse, varscan2
- COL7A1 | c.6775C>T p.P2259S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); catalogued as COSV100096574; called by muse, varscan2
- COPS2 | c.152T>C p.L51S | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54644944; called by muse, mutect2, varscan2
- CPSF1 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV62939739; called by muse, mutect2, varscan2
- CSGALNACT1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.285); catalogued as COSV59976162; called by mutect2, varscan2
- CYBB | c.100G>A p.D34N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV66085159; called by muse, mutect2, varscan2
- CYTIP | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs140145189; called by muse, mutect2, varscan2
- DCUN1D3 | c.340T>G p.F114V | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV60952955; called by muse, mutect2, varscan2
- DDX17 | c.1511A>G p.H504R | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53247223; called by muse, mutect2, varscan2
- DDX60L | c.1300T>A p.S434T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV52711669; called by muse, mutect2
- DEF8 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.302); catalogued as rs771213176, COSV51918701; called by muse, mutect2, varscan2
- DEFB121 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV66236220; called by muse, mutect2, varscan2
- DNAH10 | c.2038G>A p.E680K (on ENST00000409039; = p.E619K on NM_207437.3) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV68991415; called by muse, mutect2, varscan2
- DNAH3 | c.4792C>T p.H1598Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54515111; called by muse, mutect2, varscan2
- DNAH5 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs866784113, COSV54205135; called by muse, mutect2, varscan2
- DOK7 | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60771967; called by muse, mutect2, varscan2
- DSCAML1 | c.3949C>T p.R1317C (on ENST00000321322; = p.R1257C on NM_020693.4) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs767351865, COSV58387739; called by muse, mutect2, varscan2
- DZIP1L | c.1712C>T p.P571L | Missense Mutation (SNP) | VAF 201/808 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100551426; called by muse, mutect2, varscan2
- DZIP1L | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 205/810 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as COSV100551427; called by muse, mutect2, varscan2
- EDN3 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV61107523; called by muse, mutect2, varscan2
- EEF1G | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV61321357; called by muse, mutect2, varscan2
- ENAM | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68535698; called by muse, mutect2, varscan2
- ENAM | c.3253G>A p.D1085N | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs868635621, COSV68535702; called by muse, mutect2, varscan2
- EXPH5 | c.3934G>A p.E1312K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.12); catalogued as COSV56199748; called by muse, mutect2, varscan2
- FAT4 | c.1669C>T p.Q557* | Nonsense Mutation (SNP) | VAF 18/39 reads (46%) | catalogued as COSV67884066; called by muse, mutect2, varscan2
- FDPS | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV52739098; called by muse, mutect2, varscan2
- FER1L6 | c.2619G>A p.W873* | Nonsense Mutation (SNP) | VAF 70/325 reads (22%) | catalogued as COSV67550687; called by muse, mutect2, varscan2
- FGB | c.116G>A p.G39D | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs1560816739, COSV57417983; called by muse, mutect2, varscan2
- FGR | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64969179; called by muse, mutect2, varscan2
- FLG | c.10607G>A p.G3536E | Missense Mutation (SNP) | VAF 171/348 reads (49%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.874); catalogued as rs1279541481, COSV64240112; called by muse, mutect2, varscan2
- FLG | c.5267G>A p.G1756E | Missense Mutation (SNP) | VAF 183/381 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); catalogued as COSV64238079; called by muse, mutect2, varscan2
- FSHR | c.1270C>T p.H424Y | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs745416269, COSV58625794; called by muse, mutect2, varscan2
- GGCX | c.2114A>G p.N705S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV52087795; called by muse, mutect2, varscan2
- GLRA3 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV56860076; called by muse, mutect2, varscan2
- GNAI1 | c.51G>C p.K17N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.068); catalogued as COSV63523558, COSV63524015; called by muse, mutect2
- GPCPD1 | c.262C>T p.H88Y | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.563); catalogued as COSV66831052; called by muse, mutect2, varscan2
- GRID2 | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.049); catalogued as rs757924739, COSV56192980; called by muse, mutect2, varscan2
- GTF3C4 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1164727629, COSV64645177; called by muse, mutect2, varscan2
- HMCES | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1560074381, COSV67300292; called by muse, mutect2, varscan2
- IFT172 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53132145, COSV53132218; called by muse, mutect2, varscan2
- IGFN1 | c.2999G>A p.G1000D (on ENST00000295591 / NM_001367841.1; = p.G3457D on NM_001164586.2) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.644); catalogued as rs550548138, COSV99812643; called by muse, mutect2, varscan2
- IGSF10 | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs370254145; called by muse, mutect2, varscan2
- IL13RA2 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV54564735; called by muse, mutect2, varscan2
- IQCF1 | c.559T>A p.L187M | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); catalogued as COSV58823293; called by muse, mutect2, varscan2
- IRAK2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs774746575, COSV56530549; called by muse, mutect2, varscan2
- IYD | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57600404; called by muse, mutect2, varscan2
- KANK3 | c.1939G>A p.A647T | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV56846310; called by muse, mutect2
- KDM1A | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63087459; called by muse, mutect2, varscan2
- KIF21B | c.2471G>A p.R824H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs765068592, COSV100144277, COSV59759602; called by muse, mutect2, varscan2
- KIF3A | c.1544G>A p.R515H | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs572090360, COSV66414070; called by muse, mutect2, varscan2
- KIR3DL3 | c.572G>A p.G191E | Missense Mutation (SNP) | VAF 72/293 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as COSV99399968; called by muse, mutect2, varscan2
- KMT5B | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV58565440; called by muse, mutect2, varscan2
- KRT26 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 33/90 reads (37%) | catalogued as rs376841856; called by muse, mutect2, varscan2
- LAMA1 | c.7391C>T p.S2464F | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV67535092; called by muse, mutect2, varscan2
- LDHAL6A | c.127-1G>A p.X43_splice | Splice Site (SNP) | VAF 17/52 reads (33%) | catalogued as COSV55007532; called by muse, mutect2, varscan2
- LILRA6 | c.1115A>G p.Y372C | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); catalogued as COSV99557849; called by muse, mutect2, varscan2
- LIMK2 | c.1265C>T p.P422L | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs1177359333, COSV59182070; called by muse, mutect2, varscan2
- LRP1B | c.1847C>T p.T616I | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV67205357; called by muse, mutect2, varscan2
- LTBP1 | c.3071C>T p.P1024L (on ENST00000404816 / NM_206943.4; = p.P698L on NM_000627.4) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV63184350; called by muse, mutect2, varscan2
- LTBP2 | c.5261G>A p.G1754D | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56206885; called by muse, mutect2, varscan2
- MAD2L2 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs1408611286, COSV99335905, COSV99336015; called by muse, mutect2, varscan2
- MAJIN | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0.003); catalogued as rs1171595125, COSV54164094; called by muse, mutect2, varscan2
- MAP1LC3C | c.351G>A p.M117I | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV61803755; called by muse, mutect2, varscan2
- MARS1 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV100007422; called by muse, mutect2, varscan2
- MED23 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV63431937; called by muse, mutect2, varscan2
- MOSPD3 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV56157778, COSV99774965; called by muse, mutect2, varscan2
- MPP6 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as COSV56037212; called by muse, mutect2, varscan2
- MRC2 | c.4213C>T p.P1405S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57638632; called by muse, mutect2, varscan2
- MROH7 | c.2428T>G p.C810G | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV59870513; called by muse, mutect2, varscan2
- MUC16 | c.6229C>T p.H2077Y | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); catalogued as COSV67458682; called by muse, mutect2, varscan2
- MUC4 | c.13555C>T p.P4519S (on ENST00000463781 / NM_018406.7; = p.P283S on NM_004532.6) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV57775822; called by muse, mutect2, varscan2
- MUC6 | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771070829, COSV70139227; called by muse, mutect2, varscan2
- MXRA5 | c.3008C>A p.P1003Q | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as COSV54231367; called by muse, mutect2, varscan2
- MYH15 | c.1620G>A p.M540I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV56304541, COSV56307965; called by muse, mutect2, varscan2
- MYH2 | c.5234G>A p.G1745E | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as COSV55435510; called by muse, mutect2, varscan2
- MYO18B | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV59137428; called by muse, mutect2, varscan2
- NAGA | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV67169867; called by muse, mutect2, varscan2
- NAGLU | c.1490T>A p.L497Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56795158; called by muse, mutect2
- NASP | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs370255034; called by muse, mutect2, varscan2
- NAV2 | c.5630C>T p.S1877F (on ENST00000396087 / NM_001244963.2; = p.S1818F on NM_145117.5) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV60658342; called by muse, mutect2, varscan2
- NCKAP5 | c.5221C>T p.Q1741* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV58438230; called by muse, mutect2, varscan2
- NDC1 | c.1931G>A p.R644Q | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs777133467, COSV52335740; called by muse, mutect2, varscan2
- NDUFV1 | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1229431917, COSV59595138; called by muse, mutect2, varscan2
- NID2 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV53494901; called by muse, mutect2, varscan2
- NKAIN3 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as rs758156404, COSV60665879; called by muse, mutect2, varscan2
- NKTR | c.3683C>T p.P1228L | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV51770961; called by muse, mutect2, varscan2
- NREP | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV57404967; called by muse, mutect2, varscan2
- NUP160 | c.3160C>T p.P1054S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as COSV65854057; called by muse, mutect2, varscan2
- NUP42 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs535306272, COSV51729228, COSV51729271; called by muse, mutect2, varscan2
- NYAP2 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs866667390, COSV56002681; called by muse, mutect2, varscan2
- OBSCN | c.7328C>T p.S2443F | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV52784640; called by muse, mutect2, varscan2
- ODF3 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1475004249, COSV57293450; called by muse, mutect2, varscan2
- ODR4 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 77/140 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.453); catalogued as rs746391908, COSV55216405; called by muse, mutect2, varscan2
- OR10J1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.651); catalogued as rs867005795, COSV71129029; called by muse, mutect2, varscan2
- OR4C15 | c.523C>T p.R175C (on ENST00000314644; = p.R121C on NM_001001920.2) | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as rs267602969, COSV58951118, COSV58951281; called by muse, mutect2, varscan2
- OR4M1 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 70/473 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.231); catalogued as COSV60060447; called by muse, mutect2, varscan2
- OR6C70 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV59244735; called by muse, mutect2, varscan2
- OR7C2 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.15); catalogued as COSV50180411; called by muse, mutect2, varscan2
- OR7D2 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs753185564, COSV60139492; called by muse, mutect2, varscan2
- OR8J1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV57317673; called by muse, mutect2, varscan2
- PARP8 | c.1412C>T p.S471L | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.02); catalogued as COSV55861452; called by muse, mutect2, varscan2
- PCDH15 | c.3700G>A p.G1234S | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.025); catalogued as rs143149062; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHB1 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60633081; called by muse, mutect2, varscan2
- PCDHB1 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782127622, COSV60631692; called by muse, mutect2, varscan2
- PCDHGA7 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.314); catalogued as rs1046340065, COSV53927958; called by muse, mutect2, varscan2
- PCSK9 | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 105/348 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56161630; called by muse, mutect2, varscan2
- PDZRN4 | c.1009G>A p.D337N (on ENST00000402685 / NM_001164595.2; = p.D79N on NM_013377.4) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs750450518, COSV54197857; called by muse, mutect2, varscan2
- PHOX2B | c.862G>A p.G288R | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV56929137, COSV99891456; called by muse, mutect2, varscan2
- PITPNM3 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52594717; called by muse, mutect2, varscan2
- PMCH | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.484); catalogued as COSV59672781; called by muse, mutect2, varscan2
- PPP4R4 | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58553640; called by muse, mutect2, varscan2
- PPP4R4 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.108); catalogued as COSV58555458; called by muse, mutect2, varscan2
- PRR11 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs267604973, COSV51875893; called by muse, mutect2, varscan2
- PRR35 | c.1528C>T p.Q510* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV50312822; called by muse, mutect2, varscan2
- PRSS35 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63800396; called by muse, mutect2, varscan2
- PSG9 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 93/299 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV52484497; called by muse, mutect2, varscan2
- PTGFRN | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV101277389; called by mutect2, varscan2
- PTPN14 | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as COSV100872690; called by muse, mutect2
- RANBP9 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV50580687; called by muse, mutect2, varscan2
- RAPGEF1 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1351541945, COSV64698951; called by muse, mutect2
- RASGRF1 | c.2241G>C p.K747N | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs368915009; called by muse, mutect2, varscan2
- RCN3 | c.529C>T p.Q177* | Nonsense Mutation (SNP) | VAF 54/200 reads (27%) | catalogued as COSV54541764; called by muse, mutect2, varscan2
- RGL1 | c.129A>T p.R43S (on ENST00000360851 / NM_001297672.2; = p.R78S on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1312341027, COSV58987569; called by muse, mutect2, varscan2
- RGS18 | c.707A>T p.*236Lext*17 | Nonstop Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV66508525; called by muse, mutect2
- RNF111 | c.2605G>C p.G869R | Missense Mutation (SNP) | VAF 87/322 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62085044; called by muse, mutect2, varscan2
- RP1 | c.2315G>A p.G772E | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as COSV55111400; called by muse, mutect2, varscan2
- SEMA7A | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV56089991; called by muse, mutect2, varscan2
- SERPINA12 | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 35/118 reads (30%) | catalogued as COSV57943040; called by muse, mutect2, varscan2
- SFRP4 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as rs1329734204, COSV71412354; called by muse, mutect2, varscan2
- SLC10A7 | c.774-1G>A p.X258_splice | Splice Site (SNP) | VAF 13/50 reads (26%) | catalogued as COSV53885964; called by muse, mutect2, varscan2
- SLC35C2 | c.800C>T p.T267I | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1470936255, COSV99709371; called by muse, mutect2, varscan2
- SLC9C2 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV62945094; called by muse, mutect2, varscan2
- SNCAIP | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV54407374; called by muse, mutect2, varscan2
- SOX11 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.326); catalogued as rs767290813, COSV58984312; called by muse, mutect2, varscan2
- SPANXN2 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 170/317 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.442); catalogued as COSV65128171; called by muse, varscan2
- SPEM2 | c.376C>T p.R126C | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.193); catalogued as rs757551229, COSV60366553; called by muse, mutect2, varscan2
- SPRR3 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV54879165; called by muse, mutect2, varscan2
- ST6GAL2 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 21/74 reads (28%) | PolyPhen benign (0.13); catalogued as rs867465675, COSV64526453; called by muse, mutect2, varscan2
- TACC1 | c.2030C>T p.A677V | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV99393567; called by muse, mutect2, varscan2
- TAS2R10 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV53700850; called by muse, mutect2, varscan2
- TCERG1 | c.2608C>T p.R870* | Nonsense Mutation (SNP) | VAF 21/89 reads (24%) | catalogued as COSV57036109; called by muse, mutect2, varscan2
- TCF23 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.131); catalogued as COSV56078134; called by muse, mutect2
- TET1 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV65385656; called by muse, mutect2, varscan2
- THBS2 | c.2260-1G>A p.X754_splice | Splice Site (SNP) | VAF 9/34 reads (26%) | catalogued as COSV64678209; called by muse, mutect2, varscan2
- TLE4 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.462); catalogued as rs767747022, COSV54630035; called by muse, mutect2, varscan2
- TNFRSF11A | c.149G>A p.C50Y | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54022774; called by muse, mutect2, varscan2
- TPX2 | c.1627C>T p.R543* | Nonsense Mutation (SNP) | VAF 35/119 reads (29%) | catalogued as COSV55918670; called by muse, mutect2, varscan2
- TRIM3 | c.1531C>T p.Q511* | Nonsense Mutation (SNP) | VAF 17/68 reads (25%) | catalogued as COSV61984267; called by muse, mutect2, varscan2
- TSFM | c.947C>T p.T316I (on ENST00000323833 / NM_001172696.2; = p.T295I on NM_005726.6) | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs765598129, COSV57681207; called by muse, mutect2, varscan2
- TTN | c.41392G>A p.E13798K (on ENST00000591111; = p.E6374K on NM_003319.4) | Missense Mutation (SNP) | VAF 30/100 reads (30%) | PolyPhen possibly damaging (0.877); catalogued as COSV59978643, COSV59984701; called by muse, mutect2, varscan2
- TUT4 | c.4787C>T p.S1596L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.101); catalogued as rs763568211, COSV57112353; called by muse, mutect2, varscan2
- UBE2Q1 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 27/158 reads (17%) | catalogued as COSV52725456; called by muse, mutect2, varscan2
- UNC13C | c.6373G>A p.E2125K | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV52861373; called by muse, mutect2
- USP17L2 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs1416115357, COSV61556042; called by muse, mutect2
- VPS39 | c.253C>T p.Q85* (on ENST00000348544 / NM_001301138.2; = p.Q74* on NM_015289.5) | Nonsense Mutation (SNP) | VAF 30/83 reads (36%) | catalogued as COSV58788902; called by muse, mutect2, varscan2
- WDFY3 | c.4732C>T p.P1578S | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs867951575, COSV55693757; called by muse, mutect2, varscan2
- WDFY3 | c.2513C>G p.S838C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV55698087; called by muse, mutect2, varscan2
- WDR24 | c.913G>A p.D305N (on ENST00000248142; = p.D175N on NM_032259.4) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.082); catalogued as rs771502736, COSV50196991; called by muse, mutect2, varscan2
- WIPI1 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV50929790; called by muse, mutect2, varscan2
- XIRP1 | c.4352A>G p.E1451G | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV61137867; called by muse, mutect2, varscan2
- ZBED2 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs372487455; called by muse, mutect2, varscan2
- ZBTB49 | c.1903C>T p.H635Y | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV61924802; called by muse, mutect2, varscan2
- ZIC4 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as rs762947769, COSV67171236; called by muse, mutect2, varscan2
- ZNF302 | c.1423C>T p.P475S (on ENST00000627982; = p.P396S on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV71063680; called by muse, mutect2, varscan2
- ZNF365 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV67925277; called by muse, mutect2, varscan2
- ZNF384 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60530026; called by muse, mutect2, varscan2
- ZNF514 | c.439C>T p.L147F | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV54633739, COSV54633796; called by muse, mutect2, varscan2
- ZNF804B | c.1348G>A p.D450N | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60823579; called by muse, mutect2, varscan2
- FAM149A | c.1085_1085+1del | Frame Shift Del (DEL) | VAF 31/170 reads (18%) | called by pindel, varscan2
- FBLL1 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GUSB | c.123_139del p.D42Pfs*6 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by mutect2, pindel, varscan2
- IGHV1-3 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- IGKV1D-17 | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PRAMEF19 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 113/372 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPACA5B | c.232C>T p.Q78* | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | called by muse, varscan2
- SPATA31A1 | c.3950del p.P1317Qfs*57 | Frame Shift Del (DEL) | VAF 108/214 reads (50%) | called by mutect2, varscan2
- ABCA10 | c.4374C>T p.F1458= | Silent (SNP) | VAF 27/117 reads (23%) | catalogued as COSV52220531; called by muse, mutect2, varscan2
- ABCA8 | c.975G>A p.K325= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV52203749; called by muse, mutect2, varscan2
- ABCC6 | c.2166G>A p.L722= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as rs201193229, COSV52744798; called by muse, mutect2, varscan2
- ADAM28 | c.1641G>A p.V547= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV56099560; called by muse, mutect2, varscan2
- ADCY3 | c.1683C>T p.P561= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV53166384; called by muse, mutect2, varscan2
- ADGRV1 | c.2394C>T p.I798= | Silent (SNP) | VAF 42/188 reads (22%) | catalogued as rs986521082, COSV67983055; called by muse, mutect2, varscan2
- AHDC1 | c.3427C>T p.L1143= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs760179924, COSV99899421; called by muse, mutect2, varscan2
- AHDC1 | c.3426C>T p.I1142= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV99899423; called by muse, mutect2, varscan2
- ANGEL1 | c.1587C>T p.V529= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as rs149469500; called by mutect2, varscan2
- ANK1 | c.3246C>T p.S1082= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV55878756; called by muse, mutect2, varscan2
- ATRNL1 | c.1566C>T p.Y522= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs1236352492, COSV61802152; called by muse, mutect2, varscan2
- CELF5 | c.144C>T p.F48= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV53011147; called by muse, mutect2, varscan2
- CEP126 | c.1851G>A p.K617= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs1188531209, COSV54826515; called by muse, mutect2, varscan2
- CHRM2 | c.522G>A p.G174= | Silent (SNP) | VAF 100/213 reads (47%) | catalogued as COSV57775006; called by muse, mutect2, varscan2
- CNTNAP1 | c.552C>T p.S184= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV52849264; called by muse, mutect2, varscan2
- CREB3 | c.274C>T p.L92= | Silent (SNP) | VAF 18/36 reads (50%) | catalogued as COSV59206409; called by muse, mutect2, varscan2
- CRHR2 | c.900C>T p.S300= | Silent (SNP) | VAF 89/192 reads (46%) | catalogued as rs377428418; called by muse, mutect2, varscan2
- CSMD2 | c.1101C>T p.F367= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV53901112; called by muse, mutect2, varscan2
- CSMD3 | c.9747C>T p.F3249= (on ENST00000297405 / NM_001363185.1; = p.F3080= on NM_052900.3) | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs61754530, COSV52091126; called by muse, mutect2, varscan2
- DCAF1 | c.4362C>T p.F1454= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV60042064; called by muse, mutect2, varscan2
- EIF2B1 | c.411C>T p.V137= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as rs1213787175, COSV71194283; called by muse, mutect2, varscan2
- EPHB2 | c.534C>T p.F178= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV65861689; called by muse, mutect2, varscan2
- FAM171B | c.1815C>T p.I605= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as rs1379187384, COSV59002383, COSV59003176; called by muse, mutect2, varscan2
- FAT4 | c.10338C>T p.I3446= | Silent (SNP) | VAF 42/130 reads (32%) | catalogued as COSV58679356; called by muse, mutect2, varscan2
- FBXW12 | c.180G>A p.L60= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV56484302; called by muse, mutect2, varscan2
- FLG | c.5268G>A p.G1756= | Silent (SNP) | VAF 183/375 reads (49%) | catalogued as rs745888111, COSV100911656; called by muse, mutect2, varscan2
- FLNC | c.5004G>A p.V1668= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs779560529, COSV57953958; called by muse, mutect2, varscan2
- FNIP1 | c.462T>C p.P154= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as COSV57195288; called by muse, mutect2, varscan2
- FRG2B | c.594C>T p.I198= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV71043122; called by muse, mutect2
- FRG2C | c.597C>T p.I199= | Silent (SNP) | VAF 37/258 reads (14%) | called by muse, varscan2
- FUT9 | c.645C>T p.I215= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV56145104, COSV56148122; called by muse, mutect2, varscan2
- GRIA1 | c.1842C>T p.I614= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV53598250; called by muse, mutect2, varscan2
- GSDMC | c.195C>T p.I65= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV52694732; called by muse, mutect2, varscan2
- GUCY1A1 | c.993C>T p.I331= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV56650862; called by muse, mutect2, varscan2
- HGF | c.297C>T p.F99= | Silent (SNP) | VAF 67/157 reads (43%) | catalogued as rs368633795, COSV99736504; called by muse, mutect2, varscan2
- IGHG4 | c.276C>T p.T92= | Silent (SNP) | VAF 61/281 reads (22%) | called by muse, mutect2, varscan2
- IGKV3D-15 | c.27C>T p.F9= | Silent (SNP) | VAF 15/78 reads (19%) | called by muse, mutect2, varscan2
- KCNJ12 | c.474C>T p.A158= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs146165782, COSV59167883; called by muse, mutect2, varscan2
- KIF20B | c.3081C>T p.D1027= (on ENST00000371728 / NM_001284259.2; = p.D987= on NM_016195.4) | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as COSV53305423; called by muse, mutect2, varscan2
- KIF2B | c.183G>A p.V61= | Silent (SNP) | VAF 38/124 reads (31%) | catalogued as COSV52129276, COSV52135544; called by muse, mutect2, varscan2
- LOXL2 | c.1827C>T p.S609= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs367680908, COSV101207943; called by muse, mutect2, varscan2
- LSM3 | c.240G>A p.R80= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV60043397, COSV60043728; called by muse, mutect2, varscan2
- LTBP1 | c.3207C>T p.T1069= (on ENST00000404816 / NM_206943.4; = p.T743= on NM_000627.4) | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV55378095; called by muse, mutect2, varscan2
- MARS1 | c.1833G>A p.G611= | Silent (SNP) | VAF 39/163 reads (24%) | catalogued as COSV100007426; called by muse, mutect2, varscan2
- MEIS3 | c.975C>T p.I325= (on ENST00000558555 / NM_001346148.1; = p.I371= on NM_020160.3) | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1223053853, COSV58983224; called by muse, mutect2, varscan2
- MET | c.2856C>T p.F952= | Silent (SNP) | VAF 29/148 reads (20%) | catalogued as COSV59259668; called by muse, mutect2, varscan2
- MGAT5B | c.1191G>A p.T397= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as rs144217759; called by muse, mutect2, varscan2
- MOSPD3 | c.399C>T p.S133= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as COSV56159145; called by muse, mutect2, varscan2
- MRGPRX3 | c.777C>T p.F259= | Silent (SNP) | VAF 25/82 reads (30%) | catalogued as COSV66933493; called by muse, mutect2, varscan2
- MUC16 | c.34893G>A p.V11631= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as rs1339424862, COSV67454784, COSV67458678; called by muse, mutect2, varscan2
- NCKAP1L | c.3294C>T p.F1098= | Silent (SNP) | VAF 43/184 reads (23%) | catalogued as COSV53204339; called by muse, mutect2, varscan2
- NIPAL2 | c.903C>T p.F301= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV57840830; called by muse, mutect2
- NLRC4 | c.2578C>T p.L860= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100707111, COSV61592142; called by muse, mutect2, varscan2
- NOTCH4 | c.1473G>A p.L491= | Silent (SNP) | VAF 106/481 reads (22%) | catalogued as COSV66680020; called by muse, mutect2, varscan2
- NREP | c.156G>A p.L52= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as COSV57404983; called by muse, mutect2, varscan2
- NXF1 | c.486C>T p.F162= | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as rs374166859; called by muse, mutect2, varscan2
- OR10K1 | c.246G>A p.L82= | Silent (SNP) | VAF 161/306 reads (53%) | catalogued as COSV56871491; called by muse, mutect2, varscan2
- OR10W1 | c.690C>T p.S230= | Silent (SNP) | VAF 32/96 reads (33%) | catalogued as COSV67720353; called by muse, mutect2, varscan2
- OR13C2 | c.240C>T p.S80= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV73377732; called by muse, varscan2
- OR1A1 | c.777C>T p.F259= | Silent (SNP) | VAF 28/126 reads (22%) | catalogued as COSV58403549; called by muse, mutect2, varscan2
- OR4B1 | c.573C>T p.F191= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as COSV58882511; called by muse, mutect2, varscan2
- OR5B21 | c.633C>T p.I211= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs770041002, COSV64481761, COSV64482049; called by muse, mutect2, varscan2
- OR8H2 | c.189C>T p.F63= | Silent (SNP) | VAF 63/290 reads (22%) | catalogued as COSV57944806; called by muse, mutect2, varscan2
- P2RY14 | c.333C>T p.F111= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV56382631; called by muse, mutect2, varscan2
- PCDHB4 | c.1374C>T p.F458= | Silent (SNP) | VAF 57/203 reads (28%) | catalogued as COSV52019959; called by muse, mutect2, varscan2
- PCDHGA2 | c.2247C>T p.F749= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs1021542966, COSV53927943; called by muse, mutect2, varscan2
- PLD5 | c.1419G>A p.Q473= (on ENST00000442594; = p.Q411= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/166 reads (17%) | catalogued as COSV59150512; called by muse, mutect2, varscan2
- PPFIA4 | c.3285C>T p.F1095= (on ENST00000447715; = p.F1096= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs1283759188, COSV55313727; called by muse, mutect2, varscan2
- PTPN14 | c.2205C>T p.A735= | Silent (SNP) | VAF 12/111 reads (11%) | catalogued as COSV65286282; called by muse, mutect2, varscan2
- RAPGEF1 | c.2076C>T p.V692= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV64698959; called by muse, mutect2
- RBFOX1 | c.291G>A p.P97= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs770163669, COSV100301854, COSV60954487; called by muse, mutect2, varscan2
- SDS | c.243C>T p.V81= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs908953934, COSV57453206; called by muse, mutect2, varscan2
- SELE | c.1077C>T p.I359= | Silent (SNP) | VAF 52/97 reads (54%) | catalogued as COSV60974854; called by muse, mutect2, varscan2
- SHANK2 | c.3429C>T p.S1143= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs1396525140, COSV53586909, COSV53593653; called by muse, mutect2, varscan2
- SLC16A14 | c.333C>T p.S111= | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as COSV54617826; called by muse, mutect2, varscan2
- SLC35C2 | c.801C>T p.T267= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV99709364; called by muse, mutect2, varscan2
- SLC35F3 | c.276G>A p.R92= (on ENST00000366617 / NM_001300845.1; = p.R161= on NM_173508.4) | Silent (SNP) | VAF 49/284 reads (17%) | catalogued as rs772893092, COSV64018360; called by muse, mutect2, varscan2
- SLC44A5 | c.1182C>T p.F394= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV63762306, COSV63774612; called by muse, mutect2
- SLFN11 | c.582C>T p.F194= | Silent (SNP) | VAF 45/158 reads (28%) | catalogued as COSV57699193; called by muse, mutect2, varscan2
- SP140 | c.1809G>A p.K603= | Silent (SNP) | VAF 22/70 reads (31%) | catalogued as COSV59448489, COSV59454103; called by muse, mutect2, varscan2
- SPAG17 | c.4917C>T p.V1639= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs1330720513, COSV60456546; called by muse, mutect2, varscan2
- SPIDR | c.1035C>T p.T345= | Silent (SNP) | VAF 36/155 reads (23%) | catalogued as COSV52374035; called by muse, mutect2, varscan2
- SUPT16H | c.2991C>T p.A997= | Silent (SNP) | VAF 34/112 reads (30%) | catalogued as COSV52847995; called by muse, mutect2, varscan2
- TACC1 | c.2031C>T p.A677= | Silent (SNP) | VAF 24/179 reads (13%) | catalogued as COSV99393571; called by muse, mutect2, varscan2
- TELO2 | c.1297C>T p.L433= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV51976969, COSV99248373; called by muse, mutect2, varscan2
- TIMD4 | c.957C>T p.I319= | Silent (SNP) | VAF 114/406 reads (28%) | catalogued as rs562289861, COSV50854731; called by muse, mutect2, varscan2
- TLR6 | c.2274G>A p.R758= | Silent (SNP) | VAF 37/144 reads (26%) | catalogued as COSV67935133; called by muse, mutect2, varscan2
- TMEM104 | c.672C>T p.F224= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as rs1476572831, COSV59108814; called by muse, mutect2, varscan2
- TTC29 | c.183G>A p.R61= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV57273804; called by muse, mutect2
- TTN | c.26760C>T p.S8920= (on ENST00000591111; = p.S7993= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs727504749, COSV60128371; ClinVar: likely benign; called by muse, mutect2, varscan2
- VARS1 | c.540C>T p.A180= | Silent (SNP) | VAF 47/220 reads (21%) | catalogued as COSV65151899; called by muse, mutect2, varscan2
- VTI1A | c.615C>T p.T205= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV67579764, COSV67584981; called by muse, mutect2, varscan2
- WDR24 | c.912G>A p.R304= (on ENST00000248142; = p.R174= on NM_032259.4) | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV50197002; called by muse, mutect2, varscan2
- WDR91 | c.516C>T p.V172= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV60369290; called by muse, mutect2, varscan2
- ZBBX | c.2151G>A p.K717= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV56786961; called by muse, mutect2, varscan2
- ZSCAN10 | c.801C>T p.S267= (on ENST00000252463; = p.S322= on NM_032805.3) | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as COSV52967524; called by muse, mutect2, varscan2
- DCHS2 | n.104G>A | RNA (SNP) | VAF 11/41 reads (27%) | catalogued as COSV59723215; called by muse, mutect2, varscan2
- MASP1 | c.1303+5196C>T | Intron (SNP) | VAF 14/68 reads (21%) | catalogued as rs142630054; called by muse, mutect2, varscan2
- MIR519E | n.33T>C | RNA (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- NBPF25P | n.842G>A | RNA (SNP) | VAF 208/442 reads (47%) | called by muse, mutect2, varscan2
- SFTA3 | n.764C>T | RNA (SNP) | VAF 5/18 reads (28%) | catalogued as COSV69489155; called by muse, mutect2, varscan2
- XIRP2 | c.*592G>A | 3'UTR (SNP) | VAF 21/57 reads (37%) | catalogued as COSV99743879; called by muse, mutect2, varscan2
